Somatic mutation profile of tumor specimen ALCH-B2C2-TTP1-A (aliquot ALCH-B2C2-TTP1-A-6-0-D-A776-36) from ALCHEMIST case ALCH-B2C2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.6 years (23,242 days).
Specimen ALCH-B2C2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf51045d-2e1b-44e1-baeb-eed75b24c06b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2C2-NB1-A (Blood Derived Normal), aliquot ALCH-B2C2-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9395a21-d874-4556-8c72-d486aafb8e36

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZIC4 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288394862, COSV101268213; called by muse, mutect2
- ADAMTS4 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- CDCA5 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.991); called by muse, mutect2
- DPYD | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- MS4A18 | c.561G>A p.G187= (on ENST00000398983; = p.G189= on NM_001354471.1) | Silent (SNP) | VAF 11/275 reads (4%) | called by muse, mutect2
